Somatic mutation profile of tumor specimen TCGA-86-8279-01A (aliquot TCGA-86-8279-01A-11D-2284-08) from TCGA case TCGA-86-8279, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 46.6 years (17,032 days).
Specimen TCGA-86-8279-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d9908fe-8922-43d7-a5c1-1f36a4024ec9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8279-10A (Blood Derived Normal), aliquot TCGA-86-8279-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bacacd29-acff-4cb9-b4dd-fbbdfed97b07

The open-access MAF lists 559 somatic variants for this specimen: 425 protein-altering or splice-affecting, 117 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 367, Silent 117, Nonsense Mutation 28, Splice Site 12, Intron 10, Frame Shift Del 8, Frame Shift Ins 6, RNA 5, Splice Region 2, 3'Flank 1, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 20/30 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABAT | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.89); catalogued as COSV51621845, COSV99191048; called by muse, mutect2, varscan2
- ABCA12 | c.4797C>G p.I1599M (on ENST00000272895 / NM_173076.3; = p.I1281M on NM_015657.3) | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99790202, COSV99792342; called by muse, mutect2, varscan2
- ABCC11 | c.2189T>C p.I730T | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV100751217; called by muse, mutect2, varscan2
- ABCD2 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100429850, COSV58049378; called by muse, mutect2, varscan2
- ABCG4 | c.1365G>T p.R455S | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100267088; called by muse, mutect2, varscan2
- ABCG4 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 65/245 reads (27%) | catalogued as COSV100267089; called by muse, mutect2, varscan2
- ABTB1 | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99230188; called by muse, mutect2, varscan2
- ACCS | c.1313A>T p.N438I | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99773011; called by muse, mutect2, varscan2
- ACSF3 | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100441636; called by muse, mutect2, varscan2
- ACSM5 | c.1282C>A p.P428T | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100089658, COSV59370362; called by muse, mutect2, varscan2
- ACTL9 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100185581; called by muse, mutect2, varscan2
- ADAM11 | c.2111G>T p.W704L | Missense Mutation (SNP) | VAF 68/101 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99567883; called by muse, mutect2, varscan2
- ADAMTSL4 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.92); catalogued as rs199599791, COSV55010010; called by muse, mutect2, varscan2
- ADGRG3 | c.994A>G p.K332E | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs148924785, COSV100342716; called by muse, mutect2, varscan2
- ADGRG4 | c.6454A>G p.I2152V | Missense Mutation (SNP) | VAF 61/77 reads (79%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99797160; called by muse, mutect2, varscan2
- AHNAK2 | c.5392G>T p.A1798S | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.316); catalogued as COSV100319169; called by muse, mutect2, varscan2
- AHSG | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs1231354664, COSV99890460; called by muse, mutect2, varscan2
- AKAP11 | c.5008A>T p.S1670C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99214423; called by muse, mutect2, varscan2
- AKAP9 | c.8722T>G p.S2908A (on ENST00000359028; = p.S2884A on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.048); catalogued as COSV100663263; called by muse, mutect2, varscan2
- ALG10 | c.1422A>T p.*474Yext*3 | Nonstop Mutation (SNP) | VAF 21/153 reads (14%) | catalogued as COSV99848393; called by muse, mutect2, varscan2
- ANK2 | c.2953A>T p.R985* | Nonsense Mutation (SNP) | VAF 25/46 reads (54%) | catalogued as COSV100004563; called by muse, mutect2, varscan2
- ANKRD50 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0.053); catalogued as COSV101539059; called by muse, mutect2, varscan2
- AP001781.2 | c.431G>T p.S144I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99500405; called by muse, mutect2, varscan2
- APCS | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0.28); catalogued as COSV99661349; called by muse, mutect2, varscan2
- AQP6 | c.649T>A p.W217R | Missense Mutation (SNP) | VAF 88/134 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100210302; called by muse, mutect2, varscan2
- ARHGAP11A | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 106/172 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100853381; called by muse, mutect2, varscan2
- ARHGAP15 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99714129; called by muse, mutect2, varscan2
- ARHGAP17 | c.2107A>G p.S703G (on ENST00000289968 / NM_001006634.3; = p.S625G on NM_018054.6) | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV99254164; called by muse, mutect2, varscan2
- ASAH2 | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 118/231 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV100270193; called by muse, mutect2, varscan2
- ASH1L | c.2366C>A p.S789Y | Missense Mutation (SNP) | VAF 76/312 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV100853618; called by muse, mutect2, varscan2
- ASTN1 | c.2612G>C p.W871S | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99923336; called by muse, mutect2, varscan2
- ATF7IP | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as COSV99662256; called by muse, mutect2, varscan2
- ATP2A2 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 120/170 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100428978; called by muse, mutect2, varscan2
- AXDND1 | c.743T>A p.M248K | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100858727; called by muse, mutect2, varscan2
- BAALC | c.326T>C p.I109T (on ENST00000297574 / NM_001364874.1; = p.I74T on NM_024812.3) | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV99883941; called by muse, mutect2, varscan2
- BBS10 | c.499A>T p.R167W | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99675699; called by muse, mutect2, varscan2
- BEST2 | c.1034C>A p.A345D | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV99244716; called by muse, mutect2, varscan2
- BIRC6 | c.8442G>T p.K2814N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV101429097; called by muse, mutect2, varscan2
- BIRC6 | c.11186A>G p.H3729R | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.062); catalogued as rs771309177, COSV101429099; called by muse, mutect2, varscan2
- BLID | c.214C>A p.L72I | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.891); catalogued as COSV101601740, COSV73340316; called by muse, mutect2, varscan2
- BMP10 | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99770657; called by muse, mutect2, varscan2
- BMPER | c.446G>T p.C149F | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99780751; called by muse, mutect2, varscan2
- C14orf39 | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100408171; called by muse, mutect2, varscan2
- C16orf78 | c.107A>G p.E36G | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100148013; called by muse, mutect2, varscan2
- C16orf91 | c.311G>T p.W104L | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100113804; called by muse, mutect2, varscan2
- C1QTNF9B | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101158648; called by muse, mutect2, varscan2
- C20orf85 | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as COSV64519474, COSV64519714; called by muse, mutect2, varscan2
- CA8 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs139958315; called by muse, mutect2, varscan2
- CACNA1I | c.867G>T p.Q289H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.69); catalogued as COSV100361719; called by muse, mutect2, varscan2
- CACNA1I | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100361725; called by muse, mutect2, varscan2
- CACNA1S | c.3889G>T p.G1297W | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100755428; called by muse, mutect2, varscan2
- CACNG6 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53166530, COSV99403704; called by muse, mutect2, varscan2
- CALCA | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV100524133; called by muse, mutect2, varscan2
- CALCRL | c.409-2A>T p.X137_splice | Splice Site (SNP) | VAF 13/111 reads (12%) | catalogued as COSV101131048; called by muse, mutect2, varscan2
- CASP3 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as COSV100395101; called by muse, mutect2, varscan2
- CASS4 | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100824986, COSV64386947, COSV64387084; called by muse, mutect2, varscan2
- CCDC50 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101165368; called by muse, mutect2, varscan2
- CCN6 | c.530C>A p.S177* | Nonsense Mutation (SNP) | VAF 52/96 reads (54%) | catalogued as CM159598, COSV100037231, COSV57890521; called by muse, mutect2, varscan2
- CD53 | c.120del p.F40Lfs*26 | Frame Shift Del (DEL) | VAF 80/179 reads (45%) | catalogued as COSV54763259; called by mutect2, pindel, varscan2
- CDH20 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs749338724, COSV53003755, COSV53008290, COSV99406679; called by muse, mutect2, varscan2
- CDYL | c.1087G>T p.E363* (on ENST00000328908 / NM_001368125.1; = p.E309* on NM_004824.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/154 reads (9%) | catalogued as COSV100190304; called by muse, mutect2
- CENPT | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs776120648, COSV99535396; called by muse, mutect2, varscan2
- CFAP206 | c.704G>T p.S235I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV99740197; called by muse, mutect2, varscan2
- CHAT | c.1433C>A p.P478H | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100341027, COSV60327335; called by muse, mutect2, varscan2
- CHD7 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.012); catalogued as rs955811265, COSV71112827; called by muse, mutect2, varscan2
- CHD7 | c.8326C>T p.P2776S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs773045619, COSV101418518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRM2 | c.1360C>A p.L454I | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.668); catalogued as COSV100282078; called by muse, mutect2, varscan2
- CHST15 | c.1002G>T p.K334N | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100655398, COSV60565223; called by muse, mutect2, varscan2
- CKAP2L | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV100198538; called by muse, mutect2, varscan2
- CLCA2 | c.1467C>A p.D489E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100991773; called by muse, mutect2, varscan2
- CLCN7 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs1366250568, COSV99247704; called by muse, mutect2, varscan2
- CLDN10 | c.8G>T p.R3M | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.087); catalogued as COSV100970955; called by muse, mutect2, varscan2
- CLEC16A | c.2159G>T p.G720V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs986678550, COSV99901803; called by muse, mutect2, varscan2
- CLEC18B | c.1236G>T p.M412I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1485492352, COSV100376171, COSV60577290; called by muse, mutect2, varscan2
- CLEC1B | c.317G>T p.W106L | Missense Mutation (SNP) | VAF 63/95 reads (66%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.805); catalogued as COSV100046191; called by muse, mutect2, varscan2
- CLN8 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV100486129; called by muse, mutect2, varscan2
- CNNM3 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV100562760, COSV100562812; called by muse, mutect2, varscan2
- CNST | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100830128; called by muse, mutect2, varscan2
- CNTN5 | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99682037; called by muse, mutect2, varscan2
- COL11A1 | c.929A>G p.N310S | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs763947443, COSV100618199; called by muse, mutect2, varscan2
- COL12A1 | c.9061G>T p.G3021C | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100486697; called by muse, mutect2, varscan2
- COL12A1 | c.4000G>C p.G1334R | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100485268, COSV100486698; called by muse, mutect2, varscan2
- COL13A1 | c.976C>T p.P326S (on ENST00000398978 / NM_001130103.2; = p.P269S on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100637907; called by muse, mutect2, varscan2
- COL21A1 | c.2536G>C p.G846R | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99780500; called by muse, mutect2, varscan2
- COL24A1 | c.2896G>A p.G966R | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100994111; called by muse, mutect2, varscan2
- COL4A5 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 30/41 reads (73%) | catalogued as COSV100090310; called by muse, mutect2, varscan2
- COL4A5 | c.4321C>T p.P1441S | Missense Mutation (SNP) | VAF 78/104 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs377549534, COSV100090315; called by muse, mutect2, varscan2
- COL6A2 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100154432; called by muse, mutect2, varscan2
- COL6A6 | c.354T>A p.Y118* | Nonsense Mutation (SNP) | VAF 23/37 reads (62%) | catalogued as COSV100651037; called by muse, mutect2, varscan2
- CPED1 | c.999A>T p.K333N | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV60009665; called by muse, mutect2
- CPLX1 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100408422; called by muse, mutect2, varscan2
- CPS1 | c.2887A>G p.N963D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as rs777684462, COSV99244332; called by muse, varscan2
- CRB1 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.419); catalogued as COSV100959549; called by muse, mutect2, varscan2
- CREBBP | c.4805G>T p.R1602L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52140014, COSV99272523; called by muse, mutect2, varscan2
- CREBBP | c.4804C>T p.R1602C | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM1313429, COSV52125055; called by muse, mutect2, varscan2
- CSF1R | c.267C>G p.D89E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99643327; called by muse, mutect2, varscan2
- CSMD3 | c.10171C>A p.R3391S (on ENST00000297405 / NM_001363185.1; = p.R3222S on NM_052900.3) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV52141744, COSV99849997; called by muse, mutect2, varscan2
- CSMD3 | c.2684G>T p.C895F (on ENST00000297405 / NM_001363185.1; = p.C791F on NM_052900.3) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52280538, COSV99849998; called by muse, mutect2, varscan2
- CUBN | c.962C>A p.P321H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.579); catalogued as COSV100913673, COSV64724826; called by muse, mutect2, varscan2
- CWC27 | c.295G>T p.V99F | Missense Mutation (SNP) | VAF 121/197 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101126627; called by muse, mutect2, varscan2
- CXCL12 | c.261A>T p.L87F | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100639085; called by muse, mutect2, varscan2
- CXorf66 | c.470G>T p.R157M | Missense Mutation (SNP) | VAF 123/181 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100983952; called by muse, mutect2, varscan2
- CYP21A2 | c.904T>C p.S302P | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100926728; called by muse, varscan2
- CYP26B1 | c.1475G>T p.G492V | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.443); catalogued as COSV99135135; called by muse, mutect2, varscan2
- DACH1 | c.1458G>C p.E486D (on ENST00000619232 / NM_001366712.1; = p.E434D on NM_080759.6) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1480389257, COSV100499428; called by muse, mutect2, varscan2
- DCAF8L1 | c.1044C>A p.Y348* | Nonsense Mutation (SNP) | VAF 36/57 reads (63%) | catalogued as COSV101491565; called by muse, mutect2, varscan2
- DCLK1 | c.2118G>T p.R706S (on ENST00000360631 / NM_001330072.2; = p.R399S on NM_001195416.2) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV99713391; called by muse, varscan2
- DISP3 | c.1448G>T p.C483F | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as COSV53828176; called by muse, mutect2, varscan2
- DNAJB4 | c.414C>A p.S138R | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.072); catalogued as COSV100883509; called by muse, mutect2, varscan2
- DOCK11 | c.4769T>C p.M1590T | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99354923; called by muse, mutect2, varscan2
- DPP10 | c.441+1G>T p.X147_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100072607; called by muse, mutect2, varscan2
- DSG2 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.233); catalogued as COSV55197014, COSV55199213; called by muse, mutect2
- DSP | c.7969A>T p.T2657S | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV100673075; called by muse, mutect2, varscan2
- DST | c.5161A>G p.I1721V | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99760597; called by muse, mutect2, varscan2
- DUSP26 | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as COSV99823599; called by muse, mutect2
- DYNAP | c.194C>A p.S65* (on ENST00000321600; = p.S39* on NM_173629.3) | Nonsense Mutation (SNP) | VAF 53/86 reads (62%) | catalogued as COSV100391925; called by muse, mutect2, varscan2
- DYSF | c.913G>T p.V305L | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.57); catalogued as COSV99250883; called by muse, mutect2, varscan2
- EDC4 | c.859A>T p.K287* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100739347; called by muse, mutect2, varscan2
- EEFSEC | c.797A>C p.K266T | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99631604; called by muse, mutect2, varscan2
- EGFL8 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 65/103 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs141849753; called by muse, mutect2, varscan2
- ENPP2 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99309514; called by muse, mutect2, varscan2
- ENPP5 | c.15T>G p.F5L | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100040684; called by muse, mutect2, varscan2
- EPCAM | c.410A>C p.E137A | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV99764353; called by muse, mutect2
- ERN2 | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV99892618; called by muse, mutect2, varscan2
- ESR2 | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV99963979; called by muse, mutect2, varscan2
- EYA4 | c.1576G>T p.G526C (on ENST00000531901 / NM_001301013.1; = p.G520C on NM_004100.5) | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV100766471; called by muse, mutect2, varscan2
- FABP2 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99917024; called by muse, mutect2, varscan2
- FAM186B | c.1498T>A p.W500R | Missense Mutation (SNP) | VAF 46/69 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV99220649; called by muse, mutect2, varscan2
- FBN2 | c.6227C>A p.P2076Q | Missense Mutation (SNP) | VAF 84/126 reads (67%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.852); catalogued as COSV99331157; called by muse, mutect2, varscan2
- FCGRT | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.145); catalogued as COSV99675381; called by muse, mutect2, varscan2
- FCN1 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV100878981; called by muse, mutect2, varscan2
- FGF21 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 47/66 reads (71%) | SIFT tolerated (0.18); PolyPhen benign (0.258); catalogued as COSV99711566; called by muse, mutect2, varscan2
- FLNC | c.6456C>A p.S2152R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100368898; called by muse, mutect2, varscan2
- FLYWCH1 | c.1708G>T p.D570Y (on ENST00000253928 / NM_001308068.2; = p.D569Y on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1340738528, COSV99559359; called by mutect2, varscan2
- FMN2 | c.1433G>A p.G478D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.939); catalogued as rs756242155, COSV100147530, COSV60444738; called by muse, mutect2, varscan2
- FN1 | c.1670C>A p.P557H | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100118473, COSV60566745; called by muse, mutect2, varscan2
- FNDC1 | c.4044C>G p.I1348M | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51930848; called by muse, mutect2
- FNDC7 | c.1111+2T>A p.X371_splice | Splice Site (SNP) | VAF 91/165 reads (55%) | catalogued as COSV99601811; called by muse, mutect2, varscan2
- FPR2 | c.822T>G p.Y274* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV100389485; called by muse, mutect2, varscan2
- FREM2 | c.5378G>T p.R1793L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99751356; called by muse, mutect2, varscan2
- FRMPD4 | c.812A>G p.Q271R | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as COSV101044238; called by muse, mutect2, varscan2
- FTMT | c.534C>A p.H178Q | Missense Mutation (SNP) | VAF 93/135 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100360479, COSV58419952; called by muse, mutect2, varscan2
- GABRD | c.1159C>A p.L387M | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.766); catalogued as COSV101059589; called by muse, mutect2, varscan2
- GABRG3 | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV100410260; called by muse, mutect2, varscan2
- GAGE10 | c.17G>T p.R6I | Missense Mutation (SNP) | VAF 88/168 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101340064; called by muse, mutect2
- GALNT17 | c.1612C>A p.L538I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100356550; called by muse, varscan2
- GFM2 | c.61A>T p.N21Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.021); catalogued as COSV99713808; called by muse, mutect2, varscan2
- GGH | c.209G>T p.R70I | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99479039, COSV99479057; called by muse, mutect2, varscan2
- GLYATL2 | c.540G>C p.W180C | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99780576; called by muse, mutect2
- GNL1 | c.1571G>T p.S524I | Missense Mutation (SNP) | VAF 106/155 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV100931251; called by muse, mutect2, varscan2
- GPR139 | c.527G>T p.S176I | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV100430060; called by muse, mutect2, varscan2
- GPR158 | c.2741T>C p.L914P | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); catalogued as COSV100894393; called by muse, mutect2, varscan2
- GPR180 | c.1303A>T p.K435* | Nonsense Mutation (SNP) | VAF 36/60 reads (60%) | catalogued as COSV100979111; called by muse, mutect2, varscan2
- GPR83 | c.833A>G p.E278G | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as rs1176295264, COSV99704011; called by muse, mutect2, varscan2
- GPRC6A | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100114867; called by muse, mutect2, varscan2
- GRIN3A | c.2440C>A p.H814N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV100701904; called by muse, mutect2, varscan2
- GRK7 | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99380357; called by muse, mutect2, varscan2
- GTPBP1 | c.193-2A>T p.X65_splice | Splice Site (SNP) | VAF 18/34 reads (53%) | catalogued as COSV99323537; called by muse, varscan2
- HDC | c.1142G>T p.G381V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99984361; called by muse, mutect2, varscan2
- HDGFL2 | c.1611G>C p.E537D | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV100012462, COSV56683480; called by muse, mutect2, varscan2
- HHAT | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 39/94 reads (41%) | catalogued as COSV54807620, COSV99802836, COSV99805987; called by muse, mutect2, varscan2
- HMGCS1 | c.866G>T p.R289I | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV100285100; called by muse, mutect2, varscan2
- IFI44L | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV100654884, COSV100655148; called by muse, mutect2, varscan2
- IFNA16 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV101207093; called by muse, mutect2, varscan2
- IFNGR1 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100880544; called by muse, mutect2, varscan2
- IKZF1 | c.717C>A p.V239= | Splice Region (SNP) | VAF 25/74 reads (34%) | catalogued as COSV100498821; called by muse, mutect2, varscan2
- IL1RL1 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.025); catalogued as COSV52116491, COSV99294604; called by muse, mutect2, varscan2
- IL21R | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs758877703, COSV100560525; called by muse, mutect2, varscan2
- ITGAL | c.2244G>T p.K748N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV100776319, COSV63322641; called by muse, mutect2
- ITPRID1 | c.3040A>T p.R1014W | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV100087721; called by muse, mutect2, varscan2
- KCNB2 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 137/230 reads (60%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.007); catalogued as rs775128513, COSV73049259, COSV73051908; called by muse, mutect2, varscan2
- KCNH8 | c.2953C>T p.L985F | Missense Mutation (SNP) | VAF 112/157 reads (71%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV100111152, COSV60468759; called by muse, mutect2, varscan2
- KCNQ2 | c.1787G>T p.G596V (on ENST00000359125 / NM_172107.4; = p.G568V on NM_004518.6) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100610548, COSV100610626; called by muse, mutect2, varscan2
- KCNT1 | c.2579A>T p.N860I (on ENST00000488444; = p.N879I on NM_020822.3) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99706889; called by muse, mutect2
- KCNV1 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 47/111 reads (42%) | catalogued as COSV99819492; called by muse, mutect2, varscan2
- KDR | c.1496T>A p.V499D | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.143); catalogued as COSV99818847; called by muse, mutect2, varscan2
- KIAA1549L | c.3131T>C p.L1044P (on ENST00000321505; = p.L1341P on NM_012194.3) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99684630; called by muse, mutect2, varscan2
- KIF21B | c.4356C>A p.H1452Q (on ENST00000422435 / NM_001252100.2; = p.H1439Q on NM_017596.4) | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100145232; called by muse, mutect2, varscan2
- KIFC1 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100997147; called by muse, mutect2
- KMT2C | c.2733G>C p.K911N | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100077480; called by muse, mutect2, varscan2
- KRT26 | c.298C>A p.H100N | Missense Mutation (SNP) | VAF 112/154 reads (73%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100053396; called by muse, mutect2, varscan2
- KRTAP20-1 | c.46C>A p.L16I | Missense Mutation (SNP) | VAF 37/114 reads (32%) | PolyPhen possibly damaging (0.686); catalogued as COSV100228851; called by muse, mutect2, varscan2
- KTI12 | c.152A>T p.D51V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100860287; called by muse, mutect2, varscan2
- L3MBTL3 | c.2123G>T p.W708L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100696451, COSV62388662; called by muse, mutect2, varscan2
- LARP4B | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 40/78 reads (51%) | catalogued as COSV100295753; called by muse, mutect2, varscan2
- LCE2B | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100909346; called by muse, mutect2, varscan2
- LCE2B | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 75/266 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.389); catalogued as COSV100909348; called by muse, mutect2, varscan2
- LHFPL1 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 91/129 reads (71%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV63183089; called by muse, mutect2, varscan2
- LMAN2L | c.407A>T p.K136M | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99383678; called by muse, mutect2, varscan2
- LRP1B | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV101261816; called by muse, varscan2
- LRP1B | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101261817; called by muse, mutect2, varscan2
- LRP2 | c.11012G>T p.C3671F | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1295235890, COSV99790553; called by muse, mutect2, varscan2
- LRRC4C | c.321G>T p.L107F | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV99540010; called by muse, mutect2, varscan2
- LRRC7 | c.379G>C p.A127P (on ENST00000651989 / NM_001370785.2; = p.A94P on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99230275; called by muse, mutect2, varscan2
- LTK | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1173498026, COSV99779370; called by muse, mutect2
- MACF1 | c.8348G>T p.G2783V | Missense Mutation (SNP) | VAF 7/118 reads (6%) | catalogued as COSV99247280; called by muse, mutect2
- MADD | c.3311A>T p.K1104M | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as COSV100212100; called by muse, mutect2, varscan2
- MAP10 | c.1493G>T p.S498I | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.21); catalogued as rs971192486, COSV101406572; called by muse, mutect2, varscan2
- MAP3K11 | c.2360G>T p.R787L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.139); catalogued as COSV100442393; called by muse, mutect2, varscan2
- MARS2 | c.1481A>T p.K494M | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV99986722; called by muse, mutect2, varscan2
- MEGF6 | c.4303G>C p.D1435H | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99621502; called by muse, mutect2
- MFN1 | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1242876595, COSV99764756; called by muse, varscan2
- MFRP | c.250C>G p.P84A (on ENST00000449574; = p.P460A on NM_031433.4) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV100793553; called by muse, mutect2, varscan2
- MIA3 | c.1477A>G p.M493V | Missense Mutation (SNP) | VAF 166/281 reads (59%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100719566; called by muse, mutect2, varscan2
- MMP17 | c.1647T>A p.H549Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100861993; called by muse, mutect2, varscan2
- MRO | c.429+1G>T p.X143_splice | Splice Site (SNP) | VAF 39/59 reads (66%) | catalogued as COSV99839601; called by muse, mutect2, varscan2
- MRTFB | c.1685A>T p.N562I | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100371897; called by muse, mutect2
- MSGN1 | c.152C>A p.P51Q | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV99808871; called by muse, mutect2, varscan2
- MSGN1 | c.395G>T p.R132M | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99808874; called by muse, mutect2, varscan2
- MTFR1L | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.191); catalogued as COSV100961978, COSV65353245; called by muse, mutect2
- MTFR2 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as rs1256759715, COSV100886758; called by muse, mutect2, varscan2
- MTMR8 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as COSV100878638; called by muse, mutect2, varscan2
- MUC16 | c.31162C>A p.P10388T | Missense Mutation (SNP) | VAF 100/151 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as rs768804590, COSV101201973; called by muse, mutect2, varscan2
- MUC5AC | c.634G>T p.G212W | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0); catalogued as COSV100650732; called by muse, mutect2, varscan2
- MYH4 | c.3331A>T p.K1111* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99702431; called by muse, varscan2
- MYRF | c.325G>T p.A109S (on ENST00000278836 / NM_001127392.3; = p.A100S on NM_013279.4) | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV53886580, COSV99607995; called by muse, mutect2, varscan2
- MYT1 | c.3334A>T p.I1112F | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100115614, COSV60502066; called by muse, mutect2, varscan2
- MYT1L | c.3026G>T p.G1009V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101217473, COSV67703614; called by muse, mutect2, varscan2
- NCKAP5 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100494663; called by muse, mutect2, varscan2
- NCL | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV59546247; called by muse, mutect2, varscan2
- NEK11 | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV101273226; called by muse, mutect2, varscan2
- NEXMIF | c.1195G>C p.D399H | Missense Mutation (SNP) | VAF 90/135 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.317); catalogued as COSV99282110; called by muse, mutect2, varscan2
- NF1 | c.1792A>T p.K598* | Nonsense Mutation (SNP) | VAF 49/67 reads (73%) | catalogued as COSV100648434; called by muse, mutect2, varscan2
- NIBAN1 | c.1684A>G p.I562V | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100836656; called by muse, mutect2, varscan2
- NLRP5 | c.3571G>T p.D1191Y | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV101173923; called by muse, mutect2, varscan2
- NR4A2 | c.1714C>A p.R572S | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100277425, COSV59893212, COSV59894530; called by muse, mutect2, varscan2
- NSD3 | c.92A>T p.E31V | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as COSV100388776; called by muse, mutect2, varscan2
- OGDHL | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV100934567; called by muse, mutect2, varscan2
- OLFML2B | c.1441C>G p.P481A | Missense Mutation (SNP) | VAF 122/249 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV99669010; called by muse, mutect2, varscan2
- OR10A4 | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 69/106 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101139626, COSV65842485; called by muse, mutect2, varscan2
- OR10J5 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.213); catalogued as COSV100604856; called by muse, mutect2, varscan2
- OR10K1 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 114/325 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56874545; called by muse, mutect2, varscan2
- OR11A1 | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101010743; called by muse, mutect2, varscan2
- OR2B2 | c.475C>G p.Q159E | Missense Mutation (SNP) | VAF 103/150 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.396); catalogued as COSV100308252; called by muse, mutect2, varscan2
- OR2H2 | c.415T>C p.C139R | Missense Mutation (SNP) | VAF 111/157 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100590160, COSV63544546; called by muse, mutect2, varscan2
- OR2M2 | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.118); catalogued as COSV100677330, COSV62897854; called by muse, mutect2, varscan2
- OR2M5 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822895; called by muse, mutect2, varscan2
- OR2M7 | c.719C>G p.T240S | Missense Mutation (SNP) | VAF 202/374 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1040328593, COSV100522732; called by muse, mutect2, varscan2
- OR2T34 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV100170587; called by muse, mutect2, varscan2
- OR2Y1 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100322881; called by muse, mutect2, varscan2
- OR4A15 | c.436del p.A146Pfs*38 | Frame Shift Del (DEL) | VAF 92/363 reads (25%) | catalogued as COSV59038329; called by mutect2, pindel, varscan2
- OR4C6 | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100051895; called by muse, mutect2, varscan2
- OR5B2 | c.422G>C p.C141S | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); catalogued as COSV100223007; called by muse, mutect2, varscan2
- OR5M11 | c.528C>A p.F176L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101602072; called by muse, mutect2, varscan2
- OR8B4 | c.311G>T p.C104F | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV100635883; called by muse, mutect2, varscan2
- OR8K3 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV100449923; called by muse, mutect2, varscan2
- OTX1 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs1234043060, COSV99246599; called by muse, mutect2, varscan2
- P4HA3 | c.1552G>T p.G518* | Nonsense Mutation (SNP) | VAF 73/262 reads (28%) | catalogued as COSV100525946; called by muse, mutect2, varscan2
- PARP2 | c.1536A>C p.K512N | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99163085; called by muse, mutect2, varscan2
- PBX1 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as COSV100523022; called by muse, mutect2, varscan2
- PCDHGB7 | c.1484A>T p.D495V | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99548488; called by muse, mutect2, varscan2
- PCDHGC4 | c.1125G>T p.Q375H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99342694; called by muse, mutect2, varscan2
- PCF11 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100019361; called by muse, mutect2, varscan2
- PDILT | c.710T>C p.I237T | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as rs750927192, COSV100199872; called by muse, mutect2, varscan2
- PEAK1 | c.4792C>G p.L1598V | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100433500; called by muse, mutect2, varscan2
- PER3 | c.2611C>A p.L871M | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100728523; called by muse, mutect2, varscan2
- PEX5L | c.1540C>A p.L514I | Missense Mutation (SNP) | VAF 101/140 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99830123; called by muse, mutect2, varscan2
- PHF3 | c.3598A>G p.T1200A | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.915); catalogued as rs778781808, COSV100014104; called by muse, mutect2, varscan2
- PHLPP2 | c.3755T>G p.L1252R | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV100673861; called by muse, mutect2, varscan2
- PHRF1 | c.3832G>A p.A1278T (on ENST00000264555 / NM_001286581.2; = p.A1277T on NM_020901.4) | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1019273387, COSV52752029; called by muse, mutect2, varscan2
- PKHD1L1 | c.5327T>G p.L1776W | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV101006938; called by muse, mutect2, varscan2
- PKNOX1 | c.799C>G p.P267A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99373160; called by muse, mutect2, varscan2
- PLAGL1 | c.424C>A p.H142N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99394747; called by muse, mutect2, varscan2
- PLB1 | c.523A>T p.S175C | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV100580065; called by muse, mutect2, varscan2
- PLCB1 | c.1913G>T p.G638V | Missense Mutation (SNP) | VAF 66/103 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100572386; called by muse, mutect2, varscan2
- PLEC | c.625G>T p.D209Y (on ENST00000322810 / NM_201380.4; = p.D99Y on NM_000445.5) | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519727; called by muse, mutect2, varscan2
- PLEKHG4 | c.3086A>T p.Q1029L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100431275; called by muse, mutect2, varscan2
- POU2F2 | c.187-1G>A p.X63_splice | Splice Site (SNP) | VAF 24/57 reads (42%) | catalogued as rs756999992, COSV100657576; called by muse, mutect2, varscan2
- POU3F4 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as CM137977, COSV100937349; called by muse, mutect2, varscan2
- PPFIBP2 | c.1396G>T p.D466Y | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV100207103; called by muse, mutect2, varscan2
- PPP2R2A | c.459+1G>A p.X153_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100277390; called by muse, mutect2, varscan2
- PRDM16 | c.1846G>T p.D616Y | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99579229; called by muse, mutect2, varscan2
- PRDM2 | c.3637C>T p.L1213F | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99342866; called by muse, mutect2
- PRDM9 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57002856, COSV99691412; called by muse, mutect2, varscan2
- PRDM9 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99031450; called by muse, mutect2, varscan2
- PREX2 | c.3102G>T p.Q1034H | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.396); catalogued as COSV99910413; called by muse, mutect2, varscan2
- PRKCQ | c.1400T>C p.M467T | Missense Mutation (SNP) | VAF 54/267 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs761886595, COSV99578045; called by muse, mutect2, varscan2
- PROKR2 | c.683T>A p.F228Y | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99450716; called by muse, mutect2, varscan2
- PRPF8 | c.4688A>G p.H1563R | Missense Mutation (SNP) | VAF 83/141 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100518017; called by muse, mutect2, varscan2
- PRR16 | c.410C>A p.P137H (on ENST00000407149 / NM_001300783.2; = p.P114H on NM_016644.2) | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV101087250; called by muse, mutect2, varscan2
- PRR19 | c.26A>T p.Q9L | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as COSV100004183; called by muse, mutect2, varscan2
- PRSS1 | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs759452330, COSV100298539; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSMB11 | c.704A>T p.H235L | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV99944322; called by muse, mutect2, varscan2
- PTGDR | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.102); catalogued as rs1267967597, COSV60094917; called by muse, mutect2, varscan2
- PTPN12 | c.308A>T p.Y103F | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV99950780; called by muse, mutect2, varscan2
- PTPRC | c.1780C>A p.L594M | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100723278; called by muse, mutect2, varscan2
- PTPRD | c.3967C>T p.R1323C | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1424143158, COSV61933737; called by muse, mutect2, varscan2
- PTPRM | c.3343G>T p.A1115S | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100161023; called by muse, mutect2, varscan2
- PTPRU | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs775440824, COSV60527630; called by muse, mutect2, varscan2
- PTPRZ1 | c.5531A>T p.D1844V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101100905; called by muse, mutect2, varscan2
- PTPRZ1 | c.5744T>A p.V1915E | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101100906; called by muse, mutect2, varscan2
- RALYL | c.850C>A p.H284N | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101569525; called by muse, mutect2, varscan2
- RAP1GAP | c.474+1G>T p.X158_splice | Splice Site (SNP) | VAF 4/75 reads (5%) | catalogued as COSV51568527; called by muse, mutect2
- RAPGEF6 | c.1202A>G p.E401G | Missense Mutation (SNP) | VAF 90/130 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99728301; called by muse, mutect2, varscan2
- RASGRP4 | c.1529G>C p.R510P | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT tolerated (0.1); PolyPhen benign (0.301); catalogued as COSV53038389, COSV99385173; called by muse, mutect2, varscan2
- REG3G | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99709756; called by muse, mutect2, varscan2
- RELN | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs759711654, COSV59024775; ClinVar: uncertain significance; called by mutect2, varscan2
- REN | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as COSV99689758; called by muse, mutect2, varscan2
- RFTN2 | c.428T>A p.L143Q | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99696026; called by muse, mutect2, varscan2
- RGS19 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.693); catalogued as rs749194018, COSV100180918; called by muse, mutect2, varscan2
- RIT2 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 92/168 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56298309; called by muse, mutect2, varscan2
- RNF20 | c.2652G>A p.E884= | Splice Region (SNP) | VAF 63/137 reads (46%) | catalogued as COSV101206589; called by muse, mutect2, varscan2
- ROS1 | c.2437A>G p.R813G | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV100877787; called by muse, mutect2, varscan2
- RPL37 | c.81C>G p.Y27* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | catalogued as COSV99947734; called by muse, mutect2, varscan2
- RPS7 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV100514015, COSV100514024; called by muse, mutect2, varscan2
- RTTN | c.5776G>C p.A1926P | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV99733999; called by muse, mutect2, varscan2
- RYK | c.1579G>T p.D527Y (on ENST00000620660 / NM_001005861.2; = p.D524Y on NM_002958.4) | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99938617; called by muse, mutect2, varscan2
- RYR2 | c.12423C>A p.S4141R | Missense Mutation (SNP) | VAF 77/135 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV63686018, COSV63700741; called by muse, mutect2, varscan2
- RYR3 | c.6127G>T p.G2043W | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1450432921, COSV101214926; called by muse, mutect2, varscan2
- SCN2A | c.4888C>A p.L1630I | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99333832; called by muse, mutect2, varscan2
- SCN7A | c.786C>A p.N262K | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV101313379; called by muse, mutect2, varscan2
- SCN8A | c.2281A>G p.I761V | Missense Mutation (SNP) | VAF 74/101 reads (73%) | SIFT tolerated (0.13); PolyPhen benign (0.338); catalogued as rs544063018, COSV100634356; called by muse, mutect2, varscan2
- SEC16B | c.2221G>T p.D741Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100381672, COSV100382012; called by muse, mutect2, varscan2
- SECISBP2L | c.1376C>G p.A459G (on ENST00000559471 / NM_001193489.2; = p.A414G on NM_014701.4) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV99960242, COSV99961082; called by muse, mutect2, varscan2
- SERPINB4 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.89); PolyPhen benign (0.013); catalogued as rs1474664302, COSV61985512; called by muse, mutect2, varscan2
- SERPINE1 | c.76C>A p.H26N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99776749; called by muse, varscan2
- SETD1A | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.235); catalogued as COSV52684573, COSV99353832; called by muse, mutect2, varscan2
- SIGLEC12 | c.1002G>T p.Q334H (on ENST00000291707 / NM_053003.4; = p.Q216H on NM_033329.2) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.834); catalogued as COSV99389643; called by muse, mutect2, varscan2
- SIGLEC12 | c.389G>C p.W130S | Missense Mutation (SNP) | VAF 56/90 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV52464297, COSV99389646; called by muse, mutect2, varscan2
- SIGLEC14 | c.1134G>C p.W378C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs929496678, COSV99707996; called by muse, mutect2
- SIRPB1 | c.686T>C p.I229T | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1211670702, COSV99498634; called by muse, mutect2, varscan2
- SLC10A2 | c.456G>T p.W152C | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV55358266; called by muse, mutect2, varscan2
- SLC18A3 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100341026; called by muse, mutect2, varscan2
- SLC1A3 | c.26C>A p.P9H | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.182); catalogued as COSV99468473; called by muse, mutect2
- SLC22A10 | c.743T>A p.L248Q | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100236072; called by muse, mutect2, varscan2
- SLC25A6 | c.436G>T p.G146* | Nonsense Mutation (SNP) | VAF 62/266 reads (23%) | catalogued as COSV101195519, COSV67317573; called by muse, mutect2, varscan2
- SLC32A1 | c.1126G>T p.G376C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV99462723; called by muse, mutect2, varscan2
- SLC37A3 | c.56A>G p.H19R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV100405742; called by muse, mutect2, varscan2
- SLC44A3 | c.1072G>T p.G358* (on ENST00000271227 / NM_001114106.3; = p.G310* on NM_152369.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99598716; called by muse, mutect2, varscan2
- SLC6A19 | c.468C>A p.N156K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as rs549469162, COSV100443831; called by muse, mutect2, varscan2
- SLC6A5 | c.414G>C p.K138N | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV100116850, COSV100117212; called by muse, mutect2, varscan2
- SMAD4 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs1064796102, COSV61685043, COSV61685722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC4 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100644147; called by muse, mutect2, varscan2
- SNAP91 | c.2111C>A p.T704K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.677); catalogued as COSV99536847; called by muse, mutect2, varscan2
- SNTG2 | c.302del p.S101* | Frame Shift Del (DEL) | VAF 27/76 reads (36%) | catalogued as COSV58002322; called by mutect2, pindel, varscan2
- SNX19 | c.1724C>A p.A575D | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99773687; called by muse, mutect2, varscan2
- SORCS3 | c.3299G>T p.G1100V | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100865691; called by muse, mutect2, varscan2
- SPAM1 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763415181, COSV99773582; called by muse, mutect2, varscan2
- SPARC | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV50559844; called by muse, mutect2, varscan2
- SPATC1 | c.1362C>A p.D454E | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101085390; called by muse, mutect2, varscan2
- STARD3 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 82/110 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as rs772354583, COSV59223942, COSV99988503; called by muse, mutect2, varscan2
- STRIP1 | c.1458G>T p.E486D | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100874120; called by muse, mutect2, varscan2
- STRIP1 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 37/172 reads (22%) | catalogued as COSV100874121; called by muse, mutect2, varscan2
- SUN5 | c.925G>C p.V309L | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100644929; called by muse, mutect2, varscan2
- SYNE1 | c.23302-2A>T p.X7768_splice (on ENST00000367255 / NM_182961.4; = p.X7697_splice on NM_033071.3) | Splice Site (SNP) | VAF 10/55 reads (18%) | catalogued as COSV99582028; called by muse, mutect2, varscan2
- SYNE1 | c.7588T>C p.W2530R (on ENST00000367255 / NM_182961.4; = p.W2537R on NM_033071.3) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs752534645, COSV99582032; called by muse, mutect2, varscan2
- SYVN1 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.055); catalogued as COSV99589312; called by muse, mutect2, varscan2
- TAF4 | c.2244G>T p.K748N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.63); catalogued as COSV99435200; called by muse, mutect2, varscan2
- TANC1 | c.2718G>T p.R906S | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99715394; called by muse, mutect2, varscan2
- TAS1R2 | c.1540T>A p.C514S | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100946408; called by muse, mutect2, varscan2
- TBC1D31 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV99783280; called by muse, mutect2, varscan2
- TBX19 | c.1210G>T p.G404C | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.326); catalogued as COSV63197502; called by muse, mutect2, varscan2
- TBX20 | c.1160T>C p.L387P | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101282436; called by muse, mutect2, varscan2
- TBXT | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99752998; called by muse, mutect2, varscan2
- TCAF1 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100584736; called by muse, mutect2, varscan2
- TCERG1 | c.1225A>G p.I409V | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs372914380; called by muse, mutect2, varscan2
- TCF4 | c.1300G>T p.G434C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100611059; called by muse, mutect2, varscan2
- TDG | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV99904377; called by muse, mutect2, varscan2
- TDRD3 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99541315; called by muse, mutect2, varscan2
- TDRD5 | c.2690C>T p.S897F | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.388); catalogued as rs779603364, COSV54249313; called by muse, mutect2, varscan2
- TENM1 | c.4669C>A p.L1557M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100951178; called by muse, mutect2, varscan2
- TEX14 | c.418-1G>C p.X140_splice | Splice Site (SNP) | VAF 44/62 reads (71%) | catalogued as COSV53628139; called by muse, mutect2, varscan2
- TEX15 | c.7184C>A p.P2395H (on ENST00000256246; = p.P2778H on NM_001350162.2) | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99822274; called by muse, mutect2, varscan2
- THBS2 | c.1268G>T p.R423L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100828129; called by mutect2, varscan2
- TMEM131 | c.4720A>T p.S1574C | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.846); catalogued as COSV99489801; called by muse, mutect2, varscan2
- TMTC1 | c.1791del p.F598Lfs*12 (on ENST00000539277 / NM_001193451.2; = p.F490Lfs*12 on NM_175861.3) | Frame Shift Del (DEL) | VAF 25/55 reads (45%) | catalogued as COSV99759238; called by mutect2, pindel, varscan2
- TNN | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 37/68 reads (54%) | catalogued as COSV99513229; called by muse, mutect2, varscan2
- TNR | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs200819640; called by muse, mutect2, varscan2
- TNXB | c.12137A>T p.Q4046L (on ENST00000647633; = p.Q3799L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as COSV100926729; called by muse, mutect2
- TNXB | c.9721C>T p.Q3241* (on ENST00000647633; = p.Q2994* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 45/76 reads (59%) | catalogued as COSV100926730; called by muse, mutect2, varscan2
- TPRN | c.1385A>C p.D462A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV100285996; called by muse, mutect2, varscan2
- TRANK1 | c.7574T>C p.M2525T | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV100085046; called by muse, mutect2, varscan2
- TRHDE | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99670898, COSV99672890; called by muse, mutect2, varscan2
- TRIM14 | c.537+1G>A p.X179_splice | Splice Site (SNP) | VAF 3/41 reads (7%) | catalogued as COSV58353212; called by muse, mutect2
- TRIO | c.8084C>A p.T2695K | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100702756, COSV59988447; called by muse, mutect2, varscan2
- TRPC5 | c.684G>T p.K228N | Missense Mutation (SNP) | VAF 99/141 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV99462994; called by muse, mutect2, varscan2
- TRPS1 | c.3191G>T p.R1064I (on ENST00000220888 / NM_001330599.2; = p.R1077I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99635065; called by muse, mutect2, varscan2
- TRPV6 | c.1605G>T p.W535C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100844474; called by muse, mutect2, varscan2
- TTBK1 | c.1242C>G p.I414M | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99445077, COSV99445724; called by muse, mutect2, varscan2
- TTN | c.54205A>T p.S18069C (on ENST00000591111; = p.S10645C on NM_003319.4) | Missense Mutation (SNP) | VAF 25/187 reads (13%) | PolyPhen possibly damaging (0.794); catalogued as COSV59879782, COSV60261661; called by muse, mutect2, varscan2
- TTN | c.12103C>G p.P4035A (on ENST00000591111; = p.P3989A on NM_003319.4) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV100633475; called by muse, mutect2, varscan2
- UGT2B11 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 75/111 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as COSV101485305; called by muse, mutect2, varscan2
- UGT2B11 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 74/111 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.279); catalogued as COSV101485306, COSV71423063; called by muse, mutect2, varscan2
- USH2A | c.14172C>A p.S4724R | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs766236237, COSV100243531; called by muse, mutect2
- VAV1 | c.1410G>T p.M470I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as COSV100409533; called by muse, mutect2, varscan2
- VCAM1 | c.1896G>T p.W632C | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV99658985; called by muse, mutect2, varscan2
- VGLL3 | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.331); catalogued as COSV101052087; called by muse, mutect2, varscan2
- VPS13D | c.9116A>G p.E3039G | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV99169805; called by muse, mutect2, varscan2
- VSNL1 | c.500C>A p.T167K | Missense Mutation (SNP) | VAF 51/91 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV99723408; called by muse, mutect2, varscan2
- WDFY3 | c.6444G>C p.L2148F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV99886011; called by muse, mutect2
- WNT10B | c.1110G>T p.W370C | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99976109; called by muse, mutect2, varscan2
- WNT10B | c.1109G>T p.W370L | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99975977; called by muse, mutect2, varscan2
- XKR7 | c.1382C>A p.P461H | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.246); catalogued as COSV73813111; called by muse, mutect2, varscan2
- ZBBX | c.2123T>A p.L708Q | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV100285081; called by muse, mutect2, varscan2
- ZCCHC4 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 70/218 reads (32%) | catalogued as rs776318538, COSV100255616; called by muse, mutect2, varscan2
- ZCRB1 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 73/103 reads (71%) | catalogued as COSV99861364; called by muse, mutect2, varscan2
- ZDHHC24 | c.629G>A p.C210Y | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100130742; called by muse, mutect2, varscan2
- ZFP36 | c.690C>G p.D230E (on ENST00000594442; = p.D224E on NM_003407.5) | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.616); catalogued as COSV99954039; called by muse, mutect2, varscan2
- ZNF148 | c.1339G>T p.V447F | Missense Mutation (SNP) | VAF 66/102 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV100642195; called by muse, mutect2, varscan2
- ZNF239 | c.54A>T p.E18D | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as COSV100021948; called by muse, mutect2, varscan2
- ZNF280B | c.685G>C p.V229L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs763203400, COSV100840464; called by muse, mutect2, varscan2
- ZNF536 | c.845A>T p.K282M | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100836094; called by muse, mutect2, varscan2
- ZNF595 | c.1480A>T p.S494C | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV100227944; called by muse, mutect2, varscan2
- ZNF665 | c.1207A>T p.T403S (on ENST00000600412; = p.T468S on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV101128883; called by muse, mutect2, varscan2
- ZNF691 | c.188G>T p.W63L (on ENST00000372502; = p.W32L on NM_015911.3) | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100996169; called by muse, mutect2, varscan2
- ZNF800 | c.790A>G p.I264V | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.104); catalogued as COSV99758255; called by muse, mutect2, varscan2
- ZNF804A | c.155A>T p.D52V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100170506; called by muse, mutect2, varscan2
- ADAM10 | c.1347_1348del p.N449Kfs*5 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- AFF2 | c.2496del p.T833Qfs*26 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | called by mutect2, pindel, varscan2
- ASAH2 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- BRD3 | c.480dup p.A161Cfs*102 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- CYP11B2 | c.231del p.I78Ffs*14 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- IGKV6D-21 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNJ3 | c.1298dup p.L433Ffs*22 | Frame Shift Ins (INS) | VAF 18/117 reads (15%) | called by mutect2, pindel, varscan2
- NBPF26 | c.2194G>T p.V732F (on ENST00000620612; = p.V470F on NM_001351372.1) | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); called by muse, mutect2
- POU4F1 | c.212del p.G71Afs*15 | Frame Shift Del (DEL) | VAF 6/9 reads (67%) | called by mutect2, varscan2
- RBFOX2 | c.632_649del p.V211_N216del (on ENST00000438146 / NM_001349995.2; = p.V141_N146del on NM_014309.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 4/50 reads (8%) | called by mutect2, pindel
- SCAF11 | c.842-1G>T p.X281_splice | Splice Site (SNP) | VAF 37/51 reads (73%) | called by muse, mutect2
- SIGLEC14 | c.925dup p.I309Nfs*4 | Frame Shift Ins (INS) | VAF 31/71 reads (44%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.3022G>C p.E1008Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.065); called by mutect2, varscan2
- TG | c.410dup p.C138Vfs*28 | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | called by mutect2, varscan2
- TG | c.411delinsAT p.C138Lfs*28 | Frame Shift Ins (INS) | VAF 15/72 reads (21%) | called by mutect2*, pindel, varscan2*
- UBE2NL | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- ZNF883 | c.892dup p.C298Lfs*8 | Frame Shift Ins (INS) | VAF 67/140 reads (48%) | called by mutect2, pindel, varscan2
- ADAM12 | c.220C>A p.R74= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100901688, COSV64113554; called by muse, varscan2
- ADAMTSL2 | c.1422C>G p.L474= | Silent (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- ADARB2 | c.550C>T p.L184= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1387724951, COSV101187436; called by muse, mutect2, varscan2
- ADCY10 | c.1594C>T p.L532= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV100897134; called by muse, mutect2, varscan2
- ADGRB2 | c.4155T>A p.A1385= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99927072; called by muse, mutect2
- ADGRB2 | c.1812C>G p.A604= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99927077; called by muse, mutect2
- ADRB2 | c.528C>T p.A176= | Silent (SNP) | VAF 61/101 reads (60%) | catalogued as COSV60005229; called by muse, mutect2, varscan2
- AGAP2 | c.1092C>T p.P364= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV99224436; called by muse, mutect2, varscan2
- AKAP12 | c.4311T>A p.I1437= | Silent (SNP) | VAF 48/103 reads (47%) | catalogued as COSV99484593; called by muse, mutect2, varscan2
- ALDH16A1 | c.525C>T p.P175= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as rs1426974579, COSV99513276; called by muse, mutect2, varscan2
- ALK | c.3141C>A p.A1047= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs1314893603, COSV101202789; called by muse, mutect2, varscan2
- ARFGEF1 | c.1329A>G p.P443= | Silent (SNP) | VAF 45/87 reads (52%) | catalogued as COSV99145283; called by muse, mutect2, varscan2
- ARHGAP15 | c.390T>C p.T130= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99714125; called by muse, mutect2, varscan2
- ASAH2 | c.1428G>T p.G476= | Silent (SNP) | VAF 29/211 reads (14%) | called by muse, mutect2, varscan2
- BATF2 | c.180G>T p.R60= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100101914; called by muse, mutect2, varscan2
- BRINP2 | c.102C>G p.V34= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV100838516; called by muse, mutect2, varscan2
- BTAF1 | c.2028G>T p.R676= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV99795912; called by muse, mutect2, varscan2
- C6orf118 | c.774G>T p.T258= | Silent (SNP) | VAF 28/153 reads (18%) | catalogued as rs376983039, COSV57820355; called by muse, mutect2, varscan2
- CACNA1B | c.1794G>T p.L598= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99500270; called by muse, mutect2, varscan2
- CADM3 | c.255G>T p.L85= (on ENST00000368125 / NM_001127173.3; = p.L119= on NM_021189.5) | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV100930429, COSV63686287; called by muse, mutect2, varscan2
- CCDC178 | c.648T>A p.A216= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV100287119; called by muse, mutect2, varscan2
- CCDC88A | c.294C>T p.I98= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV99711303; called by muse, mutect2, varscan2
- CLIP4 | c.2061G>C p.P687= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV100192513; called by muse, mutect2, varscan2
- COL24A1 | c.807C>A p.P269= | Silent (SNP) | VAF 45/127 reads (35%) | catalogued as COSV100994112; called by muse, mutect2, varscan2
- COL4A4 | c.3045G>T p.G1015= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100307893; called by muse, mutect2
- COL5A1 | c.1611C>T p.P537= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1053356168, COSV100880655; called by muse, mutect2, varscan2
- COL6A3 | c.1632G>T p.R544= | Silent (SNP) | VAF 56/84 reads (67%) | catalogued as COSV99802017; called by muse, mutect2, varscan2
- DGKB | c.1539C>G p.G513= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV99343951, COSV99344202; called by muse, mutect2, varscan2
- DIPK2A | c.1182G>T p.R394= | Silent (SNP) | VAF 46/72 reads (64%) | catalogued as COSV100237498, COSV59858443; called by muse, mutect2, varscan2
- DNAH7 | c.8337A>T p.V2779= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100418022; called by muse, mutect2, varscan2
- DNAH9 | c.4989T>C p.Y1663= | Silent (SNP) | VAF 29/43 reads (67%) | catalogued as COSV99308553; called by muse, mutect2, varscan2
- DOCK2 | c.1833C>A p.L611= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99915996; called by muse, mutect2, varscan2
- ECEL1 | c.324C>A p.A108= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs758385609, COSV100459082; called by muse, varscan2
- EPHB2 | c.2601C>A p.R867= (on ENST00000400191 / NM_001309193.2; = p.R868= on NM_004442.7) | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV101007446; called by muse, mutect2, varscan2
- ERBB2 | c.678C>T p.R226= | Silent (SNP) | VAF 59/87 reads (68%) | catalogued as COSV99509309; called by muse, mutect2, varscan2
- ERICH6 | c.42G>A p.G14= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs1464747506, COSV99902088; called by muse, varscan2
- FAT3 | c.12774C>T p.G4258= | Silent (SNP) | VAF 39/218 reads (18%) | catalogued as COSV53165034; called by muse, mutect2, varscan2
- FBXO43 | c.1443A>T p.I481= | Silent (SNP) | VAF 158/361 reads (44%) | catalogued as COSV101413938; called by muse, mutect2, varscan2
- FEM1B | c.402G>C p.L134= | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as COSV100183773; called by muse, mutect2, varscan2
- FGF21 | c.474C>T p.P158= | Silent (SNP) | VAF 44/63 reads (70%) | catalogued as rs768888677, COSV99711567; called by muse, mutect2, varscan2
- FGG | c.1101T>A p.A367= | Silent (SNP) | VAF 65/104 reads (63%) | catalogued as COSV60194537; called by muse, mutect2, varscan2
- GALNT15 | c.696C>T p.L232= | Silent (SNP) | VAF 28/37 reads (76%) | catalogued as rs771624978, COSV100328050; called by muse, mutect2, varscan2
- GPAM | c.564G>T p.L188= | Silent (SNP) | VAF 44/74 reads (59%) | catalogued as COSV100788457; called by muse, mutect2, varscan2
- GPR153 | c.564G>T p.V188= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100928628; called by muse, mutect2
- IGLON5 | c.252G>T p.R84= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99570917; called by muse, mutect2, varscan2
- ITCH | c.1953T>C p.H651= (on ENST00000262650 / NM_001257137.3; = p.H610= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/181 reads (38%) | catalogued as rs1045275871, COSV99393270; called by muse, mutect2, varscan2
- ITGAM | c.1617G>T p.V539= (on ENST00000648685 / NM_001145808.2; = p.V538= on NM_000632.4) | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV99793255; called by muse, mutect2, varscan2
- KIF5A | c.1842G>A p.E614= | Silent (SNP) | VAF 28/36 reads (78%) | catalogued as COSV99673665; called by muse, varscan2
- KIFC1 | c.819G>T p.R273= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as rs1460809042, COSV100997146; called by muse, mutect2
- KIN | c.1077C>T p.S359= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs751451566, COSV65431779; called by muse, mutect2, varscan2
- KLHL20 | c.366G>T p.L122= | Silent (SNP) | VAF 49/94 reads (52%) | catalogued as COSV99268715; called by muse, mutect2, varscan2
- KLHL3 | c.1632G>T p.G544= | Silent (SNP) | VAF 26/43 reads (60%) | catalogued as COSV100553627; called by muse, mutect2, varscan2
- KRT32 | c.1158G>T p.R386= | Silent (SNP) | VAF 61/81 reads (75%) | catalogued as COSV99863220; called by muse, mutect2, varscan2
- KRTAP12-4 | c.24G>T p.S8= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV59956575; called by muse, mutect2, varscan2
- LETM2 | c.687A>T p.L229= (on ENST00000379957 / NM_001286819.2; = p.L134= on NM_144652.3) | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV99907656; called by muse, mutect2, varscan2
- LHFPL1 | c.159T>C p.P53= | Silent (SNP) | VAF 73/107 reads (68%) | catalogued as rs148325546, COSV100914532; called by muse, mutect2, varscan2
- LVRN | c.15C>G p.S5= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100773707; called by muse, mutect2, varscan2
- MAP3K11 | c.2361G>T p.R787= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV100442392; called by muse, mutect2, varscan2
- MYH4 | c.3312T>A p.L1104= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV99702432; called by muse, varscan2
- MYH6 | c.3489C>T p.I1163= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs764540332, COSV62447789; ClinVar: likely benign; called by mutect2, varscan2
- NLRP3 | c.2031G>C p.L677= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV100276762; called by muse, mutect2, varscan2
- NRXN1 | c.306G>T p.T102= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV101277057, COSV101280827; called by muse, mutect2, varscan2
- NSUN6 | c.765A>T p.L255= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV101046036, COSV66033779; called by muse, mutect2, varscan2
- ODF2 | c.741C>T p.N247= (on ENST00000434106 / NM_153433.2; = p.N223= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100655009; called by muse, mutect2, varscan2
- OR11L1 | c.762C>A p.T254= | Silent (SNP) | VAF 62/116 reads (53%) | catalogued as COSV100869502; called by muse, mutect2, varscan2
- OR1A1 | c.474C>A p.P158= | Silent (SNP) | VAF 63/91 reads (69%) | catalogued as COSV100410850; called by muse, mutect2, varscan2
- OR2F1 | c.627A>T p.T209= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV101231337; called by muse, mutect2, varscan2
- OR2L8 | c.246T>A p.S82= | Silent (SNP) | VAF 143/543 reads (26%) | catalogued as COSV100594345; called by muse, mutect2, varscan2
- OR2M3 | c.576A>T p.T192= | Silent (SNP) | VAF 119/481 reads (25%) | catalogued as rs1041084747, COSV101513535; called by muse, mutect2, varscan2
- OR4N5 | c.303C>A p.L101= | Silent (SNP) | VAF 128/188 reads (68%) | catalogued as COSV100374261; called by muse, mutect2, varscan2
- OR5L2 | c.606G>A p.V202= | Silent (SNP) | VAF 134/324 reads (41%) | catalogued as rs773360475, COSV101004436; called by muse, mutect2
- OR5T3 | c.435A>G p.S145= | Silent (SNP) | VAF 133/378 reads (35%) | catalogued as COSV100282963; called by muse, mutect2, varscan2
- OR9A2 | c.900G>A p.G300= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs769588794, COSV100628297; called by muse, mutect2, varscan2
- OR9G1 | c.633G>A p.V211= | Silent (SNP) | VAF 50/407 reads (12%) | catalogued as rs1222306875, COSV100380593; called by muse, mutect2, varscan2
- PAX7 | c.804C>T p.R268= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV100946998; called by muse, mutect2, varscan2
- PCDHB8 | c.84G>A p.A28= | Silent (SNP) | VAF 31/177 reads (18%) | catalogued as COSV50769267; called by muse, mutect2, varscan2
- PDS5B | c.3879A>T p.P1293= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV100221617; called by muse, mutect2, varscan2
- PIK3AP1 | c.456C>T p.D152= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV100226278; called by muse, mutect2, varscan2
- PKHD1 | c.8406A>G p.A2802= | Silent (SNP) | VAF 9/155 reads (6%) | catalogued as COSV100584804; called by muse, mutect2
- PNLDC1 | c.1071C>T p.L357= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV99277949; called by muse, mutect2
- POLD2 | c.1389A>T p.G463= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99789166; called by muse, mutect2, varscan2
- PRDM1 | c.1998C>A p.A666= | Silent (SNP) | VAF 60/137 reads (44%) | catalogued as COSV100959026; called by muse, mutect2, varscan2
- PRR5L | c.774C>T p.T258= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs537729454, COSV100287414; called by muse, mutect2, varscan2
- PTGER3 | c.840G>T p.T280= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100139769; called by muse, mutect2, varscan2
- PTPRB | c.2241T>C p.Y747= | Silent (SNP) | VAF 40/181 reads (22%) | catalogued as COSV99719271; called by muse, mutect2, varscan2
- PXDNL | c.2256G>C p.L752= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100686806; called by muse, mutect2, varscan2
- RAP1GAP | c.1476G>T p.P492= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV51575781; called by muse, mutect2, varscan2
- RBM27 | c.966G>T p.G322= | Silent (SNP) | VAF 79/113 reads (70%) | catalogued as COSV54589472, COSV54589523; called by muse, mutect2, varscan2
- REN | c.45G>T p.L15= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as COSV99689757; called by muse, mutect2, varscan2
- RYR2 | c.11004C>A p.I3668= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as rs1464010382, COSV100773223, COSV63705724; called by muse, mutect2, varscan2
- SCLY | c.141G>T p.T47= (on ENST00000651534; = p.T39= on NM_016510.7) | Silent (SNP) | VAF 36/47 reads (77%) | catalogued as COSV99616332; called by muse, mutect2, varscan2
- SCML4 | c.840G>T p.G280= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100940520; called by muse, mutect2, varscan2
- SCN7A | c.1417T>C p.L473= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs1424113208, COSV101313378; called by muse, mutect2
- SERPINA12 | c.675G>A p.E225= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1566808698, COSV100369855; called by muse, mutect2, varscan2
- SERPINE1 | c.36G>A p.L12= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV99776860; called by muse, varscan2
- SERPINI2 | c.666A>T p.T222= | Silent (SNP) | VAF 47/66 reads (71%) | catalogued as COSV99248548; called by muse, mutect2, varscan2
- SLC17A6 | c.699T>A p.A233= | Silent (SNP) | VAF 41/61 reads (67%) | catalogued as COSV99582511; called by muse, mutect2, varscan2
- SLC2A10 | c.405G>T p.L135= | Silent (SNP) | VAF 50/128 reads (39%) | catalogued as COSV100826414; called by muse, mutect2, varscan2
- SMAD4 | c.1218G>T p.A406= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as COSV61694986; called by muse, mutect2, varscan2
- STYXL2 | c.2046G>A p.Q682= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV99609989; called by muse, mutect2, varscan2
- SVEP1 | c.10425A>G p.P3475= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs573709228, COSV99929952; called by muse, mutect2, varscan2
- TAS1R2 | c.1311C>T p.F437= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100946410; called by muse, mutect2, varscan2
- TBC1D5 | c.1743A>G p.R581= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV99512114; called by muse, mutect2, varscan2
- TBC1D8 | c.2292C>A p.I764= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100964666; called by muse, mutect2
- TCF4 | c.1299G>C p.L433= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV100611061; called by muse, mutect2, varscan2
- TIE1 | c.2241C>A p.V747= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100992227; called by muse, mutect2, varscan2
- TMEM215 | c.333G>T p.L111= | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as COSV100713271; called by muse, mutect2, varscan2
- TMEM270 | c.666G>T p.T222= | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as COSV100260424, COSV57640071; called by muse, mutect2, varscan2
- TNKS1BP1 | c.763C>T p.L255= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100836315; called by muse, mutect2
- TOX2 | c.378C>T p.A126= (on ENST00000358131 / NM_001098798.2; = p.A75= on NM_032883.3) | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- TRDN | c.1353C>A p.T451= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100523550, COSV62125697; called by muse, mutect2
- TUBAL3 | c.252G>T p.G84= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as COSV100990597; called by muse, mutect2, varscan2
- UQCRC2 | c.381G>T p.R127= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV51673139; called by muse, mutect2, varscan2
- UTP11 | c.189A>T p.P63= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV100885004; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1395T>C p.S465= | Silent (SNP) | VAF 49/138 reads (36%) | catalogued as COSV100460420; called by muse, mutect2, varscan2
- ZNF317 | c.930G>A p.Q310= | Silent (SNP) | VAF 51/72 reads (71%) | catalogued as COSV99927391; called by muse, mutect2, varscan2
- ZNF831 | c.150C>A p.P50= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100926297; called by muse, mutect2, varscan2
- AC024598.1 | c.1130-809C>A | Intron (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100760510; called by muse, mutect2, varscan2
- AC073310.1 | n.397G>T | RNA (SNP) | VAF 29/156 reads (19%) | called by muse, varscan2
- AC092718.9 | chr16:81148188 G>T | 5'Flank (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2
- CALCA | chr11:14967711 C>A | 3'Flank (SNP) | VAF 23/42 reads (55%) | catalogued as COSV100524131; called by muse, mutect2, varscan2
- CHRM2 | c.-47+33861G>T | Intron (SNP) | VAF 15/77 reads (19%) | catalogued as COSV100282076; called by muse, mutect2, varscan2
- DCHS2 | n.8045G>T | RNA (SNP) | VAF 39/57 reads (68%) | catalogued as COSV100602493; called by muse, mutect2, varscan2
- DST | c.4297-1400G>T | Intron (SNP) | VAF 42/195 reads (22%) | catalogued as COSV99760600; called by muse, mutect2, varscan2
- DST | c.4297-4090G>T | Intron (SNP) | VAF 17/278 reads (6%) | catalogued as COSV99760602; called by muse, mutect2
- MAGEC3 | c.1124-176C>A | Intron (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100026219; called by muse, mutect2, varscan2
- MAGED2 | c.1272-292_1272-291insACA | Intron (INS) | VAF 37/54 reads (69%) | catalogued as COSV99514797; called by mutect2, pindel, varscan2
- MICAL3 | c.2241+4587G>A | Intron (SNP) | VAF 22/64 reads (34%) | catalogued as rs1227821330, COSV99263112; called by muse, mutect2, varscan2
- MIR518C | n.26T>A | RNA (SNP) | VAF 25/44 reads (57%) | called by muse, mutect2, varscan2
- NBPF25P | n.1204G>T | RNA (SNP) | VAF 175/342 reads (51%) | called by muse, mutect2, varscan2
- OR2W5 | n.1030C>T | RNA (SNP) | VAF 51/186 reads (27%) | catalogued as rs1553298837; called by muse, mutect2, varscan2
- PDE4D | c.922-6063A>T | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100402255; called by muse, mutect2, varscan2
- RBM44 | c.-98-3051A>T | Intron (SNP) | VAF 36/51 reads (71%) | catalogued as COSV100390219; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2577C>A | Intron (SNP) | VAF 39/122 reads (32%) | catalogued as COSV100315060; called by muse, mutect2, varscan2
